HCMI case HCM-WCMC-0502-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/18d012fb-77b9-4a9f-b3c7-986f9a0592d1

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Year of birth: 1973; Vital status: Dead; Days to death: 412 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Cardia, NOS; Classification of tumor: primary; Age at diagnosis: 42.9 years (15,658 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIIC; AJCC pathologic T: T3; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Prior malignancy: no; Prior treatment: Yes; Gastric esophageal junction involvement: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Andecaliximab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 34 days; Days to treatment end: 253 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX; Days to treatment start: 34 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 34 days; Days to treatment end: 253 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Neoadjuvant; Days to treatment start: 34 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 273 days; Days to treatment end: 315 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ramucirumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 273 days; Days to treatment end: 315 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 349 days.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 412 days (1.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Reflux treatment type: Proton Pump Inhibitors; Risk factor treatment: Yes; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Weight: 103.4 kg; Height: 175.3 cm; BMI: 34.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Occasional Drinker; Alcohol days per week: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0502-C15-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0502-C15-01A-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 21; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 5.
  Slide HCM-WCMC-0502-C15-01A-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 2; Percent necrosis: 1; Percent stromal cells: 22; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 5.
- Sample HCM-WCMC-0502-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0502-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
